Gene-level copy-number profile of tumor specimen TCGA-25-1877-01A from TCGA case TCGA-25-1877, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 81.1 years (29,615 days).
Specimen TCGA-25-1877-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.a6bd71ab-f853-4170-91f3-e32429cfdd43.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-1877-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 372 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4c699ac6-3201-487e-a818-9de407b9ca58

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 4,120; copy number 2: 28,616; copy number 3: 16,212; copy number 4: 7,084; copy number 5: 1,989; copy number 6: 685; copy number 7: 241; copy number 8: 129; copy number 9: 20; copy number 10: 205; copy number 11: 15; copy number 12: 25; copy number 14: 15; copy number 15: 17; copy number 17: 130; copy number 18: 93; copy number 19: 16; copy number 21: 71; copy number 23: 46.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-25-1877-01): tumor purity 0.96, ploidy 2.68, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:91,603,275–91,605,292, 1 gene: AC110774.1.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,697 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:154,220,179–154,678,345, 25 genes, copy number 5: UBAP2L, SNORA58B, HAX1, AL354980.1, RNU6-239P, RNU6-121P, AL354980.2, AQP10, ATP8B2, RNU7-57P, AL162591.1, RPSAP17, IL6R-AS1, IL6R, PSMD8P1, SHE, AL162591.2, TDRD10, UBE2Q1, UBE2Q1-AS1, AL592078.2, CHRNB2, AL592078.1, ADAR, AL606500.1.
- chr2:71,276,561–88,128,062, 309 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:163,455,568–167,825,569, 35 genes, copy number 5–7: AC079910.1, RNU7-82P, AC084017.1, MIR1263, LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1.
- chr3:168,094,049–193,176,864, 424 genes, copy number 5–8 (within-gene range 1–8) (broad region; genes not listed).
- chr3:193,241,128–198,222,513, 174 genes, copy number 5 (broad region; genes not listed).
- chr6:167,607–44,830,188, 1,323 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr6:45,328,157–50,857,662, 74 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:57,314,805–60,942,327, 22 genes, copy number 5–7 (within-gene range 4–7): PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1, AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3.
- chr6:61,679,961–62,286,225, 1 gene, copy number 18 (within-gene range 3–18): KHDRBS2.
- chr6:62,460,940–63,616,361, 18 genes, copy number 11–23: DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18.
- chr6:63,719,980–65,707,226, 1 gene, copy number 7 (within-gene range 3–7): EYS.
- chr6:64,377,795–65,838,039, 6 genes, copy number 5–7: AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4.
- chr6:75,084,326–76,092,940, 26 genes, copy number 7–12: COL12A1, COX7A2, TMEM30A, TMEM30A-DT, FILIP1, HMGB1P39, AL445465.1, U3, MIR4463, AL445465.2, UBE2V1P15, RNU1-34P, RPL26P20, H3P27, RNU6-1338P, SENP6, AL356057.1, RNU6-1016P, RN7SKP163, AL109897.1, MYO6, RNU6-155P, RNA5SP209, IMPG1, Y_RNA, RNU6-248P.
- chr6:77,343,557–79,575,530, 25 genes, copy number 5: AL365222.1, HTR1B, RPS6P7, MEI4, AL121718.1, AL450327.1, IRAK1BP1, PHIP, AL356776.1, AL356776.2, HMGN3, HMGN3-AS1, AL355796.1, Y_RNA, LCAL1, AL355379.1, AL078601.1, AL078601.2, AL391840.1, DBIP1, LCA5, AL391840.3, AL391840.2, AL451064.1, AL451064.2.
- chr8:34,174,886–38,996,824, 91 genes, copy number 5 (broad region; genes not listed).
- chr8:39,018,615–39,018,683, 1 gene, copy number 5: SNORD38D.
- chr11:68,683,779–69,162,440, 16 genes, copy number 5 (within-gene range 3–5): GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1.
- chr12:1,529,891–2,697,950, 21 genes, copy number 5 (within-gene range 4–5): WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B, CACNA1C, AC005342.1, CACNA1C-IT1, CACNA1C-IT2, AC005344.1, CACNA1C-AS4, CACNA1C-IT3, AC005293.1.
- chr14:18,333,726–23,095,614, 369 genes, copy number 10–18 (within-gene range 3–18) (broad region; genes not listed).
- chr14:28,264,390–29,372,406, 18 genes, copy number 5 (within-gene range 3–5): BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1, LINC02326, Y_RNA, AL135878.1, RNU6-864P.
- chr17:39,063,313–40,304,657, 51 genes, copy number 5 (within-gene range 3–5): PLXDC1, AC091178.2, ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6.
- chr17:40,317,698–40,318,676, 1 gene, copy number 5: AC080112.4.
- chr17:41,609,778–42,121,367, 26 genes, copy number 5: KRT16, KRT17, KRT42P, AC130686.1, EIF1, GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B, KLHL10, AC125257.1, KLHL11, ACLY, AC125257.2, TTC25, CNP, DNAJC7, NKIRAS2, ZNF385C, C17orf113, DHX58, KAT2A.
- chr17:42,122,804–42,123,352, 1 gene, copy number 5: HSPB9.
- chr19:27,638,483–28,792,871, 27 genes, copy number 5–7: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1.
- chr19:28,883,430–28,970,874, 1 gene, copy number 9 (within-gene range 4–9): LINC00906.
- chr19:28,949,437–37,304,395, 290 genes, copy number 6–23 (within-gene range 2–23) (broad region; genes not listed).
- chr19:39,236,433–39,255,269, 4 genes, copy number 18: IFNL3P1, IFNL3, IFNL4, MSRB1P1.
- chr19:39,553,034–41,261,766, 91 genes, copy number 15–21 (broad region; genes not listed).
- chr20:23,655,225–34,347,785, 224 genes, copy number 5 (broad region; genes not listed).
- chr20:34,384,165–34,402,696, 2 genes, copy number 5: Y_RNA, CDC42P1.

Autosomal genes at a single copy (total copy number 1): 1,699. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
